Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70T, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70T-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology [	Final Results
Surgical Pathology	Final
CASE NUMBER:	
DIAGNOSIS:	

1. Right portal lymph node, frozen section: One lymph node, no tumor seen (0/1).

2. Tumor, right retroperitoneal, resection: Paraganglioma (Extra-adrenal pheochromocytoma). See Note.

NOTE: In focal areas, the tumor is seen very close/at the inked surface.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology, They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History:
palpitations, tremors, retroperitoneal mass Specimen Taken For
Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: paraganglioma Post-Operative
Diagnosis: same
Operative Findings: lobulated, circumscribed retroperitoneal mass

SPECIMENS SUBMITTED: 1. ROUTINE + 3FR.SLIDES, Right portal lymph node
()
2. TUMOR, Right retroperitoneal

INTRAOPERATIVE CONSULTATION: Received fresh from OR with the patient name, medical record number and further specified as "right portal lymph node is a soft tissue yellow-pink fragment 1.4 x 1.2 x 0.7 cm. Bisected and frozen in toto as

Diagnosis: One lymph node, no tumor seen.

The frozen section was done by

GROSS DESCRIPTION: Received are specimen labeled with the patient's name, medical record number, and further specified as follows:

1. "Right portal lymph node. The specimen is transferred from a green

[page 2 of 2]
Final Results

Surgical Pathology

cassette to an orange cassette labeled

2. "Right retroperitoneal tumor". The specimen consists of a mass measuring 6.4 cm x 5.3 cm x 3.8 cm with a nodular external surface. The specimen is inked in black and serially sectioned. Approximately 50% of tissue is procured for Procurement
cm x 0.8 cm of tissue is procured for Gross
was done by
photographs are taken. The specimen is received in Surgical Pathology and matches the above description. The cut surface is variegated with hemorrhagic areas and yellow tissue that is extremely nodular. Representative sections are placed in white cassettes labeled
represents the section that was frozen as an internal control by Surgery did not require this as a frozen section.

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Primary / Tumor Site Discrepancy		☒

lw 7/25/13
7/25/13

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Do not file in Medical Record

Requested By:

Source: NCI Genomic Data Commons file 2aeba2ec-b370-4e04-aa7e-26480945c12f (TCGA-QR-A70T.75661541-4302-42EE-A60B-90F6E79FCC79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).